Somatic mutation profile of tumor specimen MP2PRT-PAVDAU-TMP1-A (aliquot MP2PRT-PAVDAU-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAVDAU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.0 years (2,911 days).
Specimen MP2PRT-PAVDAU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0e2a932-aa78-45f9-99ae-64202f87e84b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDAU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDAU-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/053f6783-fe77-49f0-a348-c41f925717f1

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FIGN | c.1051A>G p.M351V | Missense Mutation (SNP) | VAF 79/680 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1265329633; called by muse, mutect2, varscan2
- GCN1 | c.6884C>T p.S2295L | Missense Mutation (SNP) | VAF 75/489 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771890293; called by muse, mutect2, varscan2
- IGKV4-1 | chr2:88886152 del CT | Frame Shift Del (DEL) | VAF 37/73 reads (51%) | catalogued as rs750336010; called by pindel*, varscan2
- ABCA6 | c.1640A>C p.E547A | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- CHSY3 | c.2509C>T p.H837Y | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT tolerated (0.86); PolyPhen benign (0.091); called by muse, mutect2
- CNTNAP5 | c.576G>T p.R192S | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GOLGA8T | c.1418T>A p.V473E | Missense Mutation (SNP) | VAF 68/458 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- HCRTR2 | c.1100T>A p.L367H | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRC53 | c.2674C>T p.H892Y | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SPTBN2 | c.4952G>T p.S1651I | Missense Mutation (SNP) | VAF 14/464 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- VN1R2 | c.593G>T p.W198L | Missense Mutation (SNP) | VAF 191/397 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- OR6X1 | c.753G>A p.G251= | Silent (SNP) | VAF 135/282 reads (48%) | called by muse, mutect2, varscan2
- OR8B12 | c.156T>G p.S52= | Silent (SNP) | VAF 50/300 reads (17%) | called by muse, mutect2, varscan2
- SNAP25 | c.462C>T p.S154= | Silent (SNP) | VAF 168/412 reads (41%) | catalogued as rs201639889, COSV54771953, COSV54772616; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF565 | c.6C>T p.R2= | Silent (SNP) | VAF 63/482 reads (13%) | called by muse, mutect2, varscan2
